Gene-level copy-number profile of tumor specimen C3L-02384-01 from CPTAC case C3L-02384, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage II; FIGO stage: Stage II; Tumor grade: G3; Age at diagnosis: 81.4 years (29,731 days).
Specimen C3L-02384-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 6c1f4de1-4391-468d-84b3-fe2f9ee6f30c.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-02384-74 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,241 have no estimate.
https://portal.gdc.cancer.gov/files/4587fa94-127e-4b5a-bd97-2794f496aec3

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 65; copy number 1: 10,371; copy number 2: 43,880; copy number 3: 3,081; copy number 4: 494; copy number 5: 335; copy number 6: 36; copy number 7: 21; copy number 9: 11; copy number 10: 78; copy number 11: 9; copy number 27: 1.

Homozygous deletions (total copy number 0; autosomes only): 65 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr15:19,878,555–20,866,314, 46 genes: AC138701.1, RNU6-978P, AC138701.2, AC127381.2, IGHV1OR15-9, SLC20A1P3, IGHV1OR15-2, IGHV3OR15-7, IGHD5OR15-5A, IGHD4OR15-4A, IGHD3OR15-3A, IGHD2OR15-2A, IGHD1OR15-1A, FAM30B, AC127381.1, BCAR1P1, RN7SL584P, AC087386.1, AC087386.2, BMS1P15, RHPN2P1, CHEK2P2, AC026495.1, HERC2P3, AC023310.1, GOLGA6L6, AC023310.3, GOLGA8CP, RN7SL759P, SPATA31E2P, AC023310.2, IGHV1OR15-6, AC023310.4, NBEAP1, AC131280.1, AC012414.4, RNU6-498P, AC012414.2, AC012414.3, LONRF2P3, AC012414.6, GRAMD4P5, AC012414.1, MIR3118-2, POTEB2, RNU6-749P.
- chr15:20,901,441–21,260,147, 19 genes: ZNF519P2, NF1P1, MIR5701-1, LINC01193, OR11J2P, OR11J5P, IGHD5OR15-5B, IGHD4OR15-4B, IGHD3OR15-3B, IGHD2OR15-2B, IGHD1OR15-1B, FAM30C, AC037471.1, BCAR1P2, RN7SL400P, AC126335.1, AC126335.2, BMS1P16, NBEAP4.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 491 genes in 22 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:113,157,325–113,563,298, 12 genes, copy number 5: PSD4, AC016683.1, PAX8-AS1, PAX8, AC016745.1, IGKV1OR2-108, AC016745.2, CBWD2, FOXD4L1, LINC01961, PGM5P4-AS1, PGM5P4.
- chr2:163,152,251–163,289,096, 2 genes, copy number 7: RPL7P61, RNU6-627P.
- chr2:166,403,573–167,716,065, 8 genes, copy number 5: SCN7A, AC074101.1, XIRP2, AC092601.1, XIRP2-AS1, AC073050.1, RNU7-148P, CTAGE14P.
- chr2:172,735,274–175,463,180, 52 genes, copy number 5 (within-gene range 3–5): RAPGEF4, ALDH7A1P2, MAP3K20, MAP3K20-AS1, RPS2P18, AC092573.1, CDCA7, JPT1P1, CBY1P1, PPIAP66, AC013410.1, AC013410.2, AC106900.1, RPL5P7, SP3, AC016737.1, AC016737.2, LINC01960, RPSAP24, OLA1, AC013467.1, RN7SL65P, Y_RNA, LRRC2P1, HNRNPA1P39, LINC01305, AC018470.1, SP9, CIR1, SCRN3, GPR155, AC010894.1, RPA3P1, AC010894.4, AC010894.2, RNU6-5P, WIPF1, AC010894.3, H3P6, CHRNA1, CHN1, RNU6-763P, RNU6-1290P, RPL21P31, ATF2, AC007435.1, MIR933, AC096649.1, ATP5MC3, Y_RNA, RPS15AP14, AC093459.1.
- chr2:176,338,637–186,849,208, 143 genes, copy number 5–6 (broad region; genes not listed).
- chr2:187,003,220–191,847,088, 68 genes, copy number 5–11 (within-gene range 1–11) (broad region; genes not listed).
- chr2:192,749,845–197,786,762, 60 genes, copy number 10: PCGEM1, RPS17P8, AC013401.2, SLC44A3P1, DNAJC17P1, SEC61GP1, AC068135.2, AC068135.1, GLULP6, HNRNPA1P47, LINC01821, AC106883.1, Metazoa_SRP, AC006196.1, LINC01790, AC010983.1, AC104823.1, AC064834.1, RNU6-169P, LINC01825, LINC01827, SLC39A10, AHCYP5, RNU6-915P, DNAH7, E2F3P2, AC114760.1, STK17B, AC114760.2, HECW2, HECW2-AS1, RN7SL820P, CCDC150, AC068544.1, GTF3C3, C2orf66, AC012486.1, PGAP1, ANKRD44, HNRNPA3P15, RPL4P7, ANKRD44-AS1, ANKRD44-IT1, ATP5MC2P3, AC010746.2, NPM1P46, SF3B1, AC010746.1, RNU6-1029P, COQ10B, HSPD1, HSPE1, HSPE1-MOB4, MOB4, AC020550.1, RFTN2, AC020550.2, AC011997.1, MARS2, BOLL.
- chr3:13,549,125–13,746,638, 2 genes, copy number 11–27: FBLN2, LINC00620.
- chr6:151,656,691–152,129,619, 4 genes, copy number 5 (within-gene range 2–5): ESR1, AL356311.1, AL078582.2, AL078582.1.
- chr7:75,156,639–75,410,996, 19 genes, copy number 5–6 (within-gene range 3–6): NCF1C, GTF2IP1, PHBP6, AC211486.5, AC211486.2, AC211486.4, SPDYE13, PMS2P10, Y_RNA, SPDYE14, AC211486.3, Y_RNA, SPDYE15, PMS2P2, Y_RNA, STAG3L1, Y_RNA, AC211486.1, TRIM73.
- chr10:69,403,903–69,596,436, 12 genes, copy number 5: TACR2, ATP5MC1P7, TSPAN15, AC016821.1, TMEM256P1, NEUROG3, AL450311.1, MTATP6P23, MTCO2P23, MTCO1P23, MTND2P15, MTND1P20.
- chr12:50,953,922–50,970,506, 1 gene, copy number 6 (within-gene range 3–6): HIGD1C.
- chr12:50,979,401–51,173,135, 10 genes, copy number 6: SLC11A2, RNU6-87P, RNU6-1273P, LETMD1, CSRNP2, TFCP2, RPL35AP29, PHBP19, Y_RNA, RNU6-199P.
- chr17:28,662,198–28,951,771, 34 genes, copy number 5 (within-gene range 3–5): SUPT6H, AC010761.3, PROCA1, RAB34, RPL23A, SNORD42B, AC010761.1, SNORD4A, SNORD42A, SNORD4B, TLCD1, NEK8, AC010761.6, AC010761.2, TRAF4, AC010761.4, AC010761.5, FAM222B, RPL31P58, Y_RNA, AC024267.2, ERAL1, AC024267.1, MIR451A, MIR451B, MIR144, MIR4732, FLOT2, AC024267.3, AC024267.6, DHRS13, PHF12, AC024267.4, AC024267.5.
- chr17:39,461,486–39,919,854, 19 genes, copy number 7–11 (within-gene range 2–11): CDK12, RNU6-233P, AC009283.1, NEUROD2, AC087491.1, PPP1R1B, STARD3, TCAP, PNMT, PGAP3, ERBB2, MIR4728, MIEN1, GRB7, IKZF3, KRT8P34, AC090844.1, ZPBP2, GSDMB.
- chr17:48,382,371–48,606,414, 14 genes, copy number 6–7 (within-gene range 2–7): U3, AC036222.1, Y_RNA, HOXB1, HOXB2, HOXB-AS1, HOXB3, HOXB-AS3, HOXB-AS2, HOXB4, AC103702.1, MIR10A, HOXB5, HOXB6.
- chr17:58,324,472–58,415,766, 1 gene, copy number 5 (within-gene range 2–5): TSPOAP1-AS1.
- chr17:58,345,175–58,557,799, 8 genes, copy number 5 (within-gene range 2–5): SUPT4H1, AC004687.2, RNF43, HSF5, SETP3, MTMR4, SEPTIN4-AS1, SEPTIN4.
- chr19:39,984,134–40,299,584, 14 genes, copy number 5: ZNF546, AC007842.1, ZNF780B, AC005614.2, ZNF780A, AC005614.1, VN1R96P, MAP3K10, TTC9B, CCNP, AKT2, AC118344.1, MIR641, RNU6-945P.
- chr22:18,361,820–18,391,105, 2 genes, copy number 9: FAM230J, AC011718.1.
- chr22:18,527,802–18,530,573, 1 gene, copy number 5: TMEM191B.
- chr22:18,605,355–18,625,289, 5 genes, copy number 10–11: AC023490.1, RN7SKP131, RIMBP3, Metazoa_SRP, SUSD2P2.

Autosomal genes at a single copy (total copy number 1): 8,029. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
